Gene-level copy-number profile of tumor specimen HCM-CSHL-0434-C24-06A from HCMI case HCM-CSHL-0434-C24, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Extrahepatic bile duct; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 61.0 years (22,282 days).
Specimen HCM-CSHL-0434-C24-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e22382a5-1760-4084-8242-fff83b22a700.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0434-C24-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,708 have no estimate.
https://portal.gdc.cancer.gov/files/a2e5eb3e-f772-48ed-a46c-b63dff2814d4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,966; copy number 2: 55,613; copy number 3: 334; copy number 7: 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:64,091–79,775, 2 genes, copy number 7: AC144568.1, AC144568.2.

Autosomal genes at a single copy (total copy number 1): 110. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
